Somatic mutation profile of tumor specimen TARGET-40-NAAHDE-02A (aliquot TARGET-40-NAAHDE-02A-01D) from TARGET case TARGET-40-NAAHDE, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.1 years (4,048 days).
Specimen TARGET-40-NAAHDE-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aeedc2df-5f6a-407d-b8e3-7bfcb76aa141.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHDE-10A (Blood Derived Normal), aliquot TARGET-40-NAAHDE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e113960-3e4c-4cb8-aa08-f0ef692ca586

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.10547G>C p.R3516T | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1267251377, COSV54207318; called by muse, mutect2
- MUC16 | c.15083G>A p.W5028* | Nonsense Mutation (SNP) | VAF 7/151 reads (5%) | catalogued as COSV67447329; called by muse, mutect2
- MUC4 | c.5701G>C p.D1901H | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.866); catalogued as rs1314690012, COSV62148079; called by muse, varscan2
- MUC4 | c.5461G>C p.D1821H | Missense Mutation (SNP) | VAF 59/493 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.866); catalogued as rs71617313; called by muse, varscan2
- MUC4 | c.5375G>C p.R1792P | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.318); catalogued as rs774527434; called by muse, varscan2
- MUCL3 | c.890A>C p.N297T | Missense Mutation (SNP) | VAF 64/423 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868295857, COSV58516355; called by muse, mutect2
- RSL1D1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1490268343; called by muse, mutect2, varscan2
- ZNF90 | c.1601C>A p.A534E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs186928119, COSV69001934, COSV69002776; called by muse, mutect2
- CTC1 | c.1919A>G p.Q640R | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- DNAH3 | c.7651T>A p.F2551I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2
- FRMPD4 | c.3049G>A p.G1017R | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MGA | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- TOP1 | c.1837C>A p.P613T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SSPOP | n.13872G>A | RNA (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
